Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2V, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2V-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

2008-3
Fibromyxosarcoma 8811/3
Site Back NOS 049.6
JW 3/10/14

....

Clinical Diagnosis & History:

with right paraspinal mass. CNB = myxofibrosarcoma.

Specimens Submitted:

1: SP:Soft tissue, right paraspinal sarcoma, excision

DIAGNOSIS:

1. SOFT TISSUE, RIGHT PARASPINAL SARCOMA, EXCISION:
- HIGH GRADE MYXOFIBROSARCOMA
- TUMOR MEASURES 6.3 CM GREATEST DIMENSION, INVOLVES SUBCUTANEOUS FIBROADIPOSE TISSUE, AND COMES WITHIN 0.07 CM OF DEEP MARGIN (OTHER MARGINS WIDELY FREE OF TUMOR); DEEP FASCIA IS NOT INVOLVED BY SARCOMA.
- NO TUMOR NECROSIS SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is received fresh, labeled "right paraspinal sarcoma, long stitch-right lateral, short-superior". It consists of an ellipse of skin with subcutaneous soft tissue measuring 16.5 x 11.0 x 3.4 cm. Lateral half of surgical margin is inked blue and medial half is inked green. The skin surface is tan and unremarkable grossly. Sections show a well-circumscribed yellow-tan lobulated soft and myxoid mass measuring 6.3 x 4.5 x 4.2 cm. The tumor is less than 0.1 cm from the deep margin, which is inked black.

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
Skeletal muscle is identified on the deep aspect of the specimen. Fresh tissue is submitted for TPS. Gross photographs are taken. Representative sections are submitted.

Summary of sections:

ST-superior tip
IT-inferior tip
T-tumor

Summary of Sections:

Part 1: SP:Soft tissue, right paraspinal sarcoma, excision

Block	Sect.	Site	PCs
1		it	1
1		st	1
7		t	7

** End of Report **

Criteria	hu 1/22/14	Yes	No
Primary Tumor Site Discrepancy	Paraspinal		✓

Source: NCI Genomic Data Commons file 074eee13-0175-49f2-a1b7-4bb0f83a60df (TCGA-DX-AB2V.09FCE446-FC8E-4039-A2C3-179F5E2E9BD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).